Somatic mutation profile of tumor specimen TCGA-XD-AAUH-01A (aliquot TCGA-XD-AAUH-01A-42D-A40W-08) from TCGA case TCGA-XD-AAUH, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.1 years (20,858 days).
Specimen TCGA-XD-AAUH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e76ad64-3112-49b0-8507-6fd99cc1350a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XD-AAUH-11A (Solid Tissue Normal), aliquot TCGA-XD-AAUH-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82f39543-7e8d-4efd-9364-acdde4e0270d

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100181225; called by muse, mutect2
- FGL2 | c.989T>A p.L330* | Nonsense Mutation (SNP) | VAF 15/484 reads (3%) | catalogued as COSV50380465; called by muse, mutect2
- HEATR3 | c.1594T>C p.S532P | Missense Mutation (SNP) | VAF 17/567 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99590157; called by muse, mutect2
- INHBA | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 22/376 reads (6%) | catalogued as COSV54220761, COSV99637475; called by muse, mutect2
- PLEKHH2 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99175209; called by muse, mutect2
- PTPRG | c.3048G>T p.R1016S | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99877249; called by muse, mutect2
- SMC5 | c.1525T>G p.L509V | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100747184; called by muse, mutect2
- SPESP1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 16/419 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs1426607850, COSV99534907; called by muse, mutect2
- CNTNAP5 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DYRK1A | c.1701T>A p.G567= | Silent (SNP) | VAF 16/398 reads (4%) | catalogued as COSV100118363; called by muse, mutect2
- KIR3DL3 | c.321G>A p.S107= | Silent (SNP) | VAF 32/840 reads (4%) | catalogued as rs1436815764; called by muse, mutect2
- MYH11 | c.282G>A p.T94= | Silent (SNP) | VAF 16/485 reads (3%) | catalogued as rs759914132, COSV100260470; called by muse, mutect2
- TMEM132D | c.127C>T p.L43= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV101399793; called by muse, mutect2
